Somatic mutation profile of tumor specimen PCProject_0234_T1_WES (aliquot PCProject_0234_T1_WES_1) from CMI case PCProject_0234, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.4 years (21,320 days).
Specimen PCProject_0234_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d83001bf-0393-4cbd-979e-087381f2fe34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0234_SALIVA (Saliva), aliquot PCProject_0234_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97cb1c54-0068-4806-96fa-cefbf7ed62d2

The open-access MAF lists 630 somatic variants for this specimen: 411 protein-altering or splice-affecting, 144 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 343, Silent 144, Intron 41, Frame Shift Del 36, Nonsense Mutation 12, 3'UTR 11, Frame Shift Ins 8, 5'Flank 7, 5'UTR 7, RNA 7, In Frame Del 5, Splice Site 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANTXR2 | c.1073dup p.A359Cfs*13 | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | catalogued as rs312262690; ClinVar: pathogenic; called by pindel, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 30/164 reads (18%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRPF1 | c.2794del p.Q932Sfs*5 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as rs762904815, COSV57403691; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.216del p.V73Wfs*50 | Frame Shift Del (DEL) | VAF 46/292 reads (16%) | catalogued as rs730882018; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABAT | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs761782312, COSV51628589; ClinVar: uncertain significance; called by muse, varscan2
- ABHD16B | c.242G>C p.S81T | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs758497660; called by muse, mutect2, varscan2
- ADAMTS18 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs765623782, COSV51403298; called by muse, mutect2, varscan2
- ADAMTSL4 | c.963del p.T322Lfs*21 | Frame Shift Del (DEL) | VAF 17/87 reads (20%) | catalogued as rs748115277, COSV55000781; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2483del p.P828Rfs*120 | Frame Shift Del (DEL) | VAF 56/368 reads (15%) | catalogued as rs771762024; called by pindel, varscan2
- ADGRA3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs750505698, COSV51561810; called by muse, mutect2, varscan2
- AGAP1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 75/396 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs746523053; called by muse, mutect2, varscan2
- AHDC1 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs754239206, COSV99898937; called by muse, mutect2, varscan2
- ANAPC5 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55842202; called by muse, mutect2
- ANKRD52 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 104/622 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs777085738; called by muse, mutect2, varscan2
- ANKS1A | c.2404G>A p.V802M | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774617212; called by muse, mutect2, varscan2
- ANPEP | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760700420, COSV100263626; called by muse, mutect2, varscan2
- ARHGAP21 | c.4454C>T p.T1485M | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.238); catalogued as rs569426222, COSV57603820; called by muse, mutect2, varscan2
- ARHGEF19 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs376152196; called by muse, mutect2
- ATP10D | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs773685085, COSV56704660; called by muse, mutect2, varscan2
- ATP2B4 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1184347672; called by muse, mutect2, varscan2
- BRINP2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1221762863, COSV64176751; called by muse, mutect2, varscan2
- C10orf71 | c.3847G>A p.G1283R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047765296, COSV60504292, COSV60514472; called by muse, mutect2, varscan2
- C12orf43 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1436788426; called by muse, mutect2
- C20orf141 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.676); catalogued as rs145477107; called by mutect2, varscan2
- C4orf54 | c.3830G>A p.R1277H | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1329020907; called by muse, mutect2, varscan2
- C5AR1 | c.1007del p.T336Sfs*49 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | catalogued as COSV61892657; called by mutect2, pindel, varscan2
- CACNA1B | c.6071C>T p.T2024M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs1317101682, COSV53129778; called by muse, mutect2, varscan2
- CACNA1I | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs747408421, COSV60802364; called by muse, mutect2, varscan2
- CAMK2A | c.1036C>T p.R346W (on ENST00000348628 / NM_171825.2; = p.R357W on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs745982580; called by muse, mutect2, varscan2
- CAMK2A | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.332); catalogued as rs1449666180, COSV100652019, COSV62246426; called by muse, mutect2
- CCDC42 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs571535127, COSV53449391; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 21/90 reads (23%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC51 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs930556681; called by muse, mutect2, varscan2
- CDC42BPG | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs371471295, COSV61345901; called by muse, mutect2, varscan2
- CDC42EP1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs947968701; called by muse, mutect2, varscan2
- CDK8 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67419796; called by muse, mutect2, varscan2
- CECR2 | c.3626C>T p.P1209L (on ENST00000342247 / NM_001290047.2; = p.P1025L on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs374388183, COSV52838721; called by muse, mutect2, varscan2
- CENPJ | c.2977C>T p.R993C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs141752731; called by muse, varscan2
- CEP170B | c.631G>A p.A211T (on ENST00000453495; = p.A140T on NM_015005.3) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs1194840601; called by muse, mutect2, varscan2
- CEP170B | c.1817C>T p.S606L (on ENST00000453495; = p.S535L on NM_015005.3) | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1393915524; called by muse, mutect2
- CEP72 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as rs1272077927; called by muse, mutect2, varscan2
- CFAP74 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 43/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200040017; called by muse, mutect2, varscan2
- CH25H | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1304689271, COSV64092306; called by muse, mutect2
- CHD5 | c.2339A>G p.Y780C | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1250224589; called by muse, mutect2, varscan2
- CHPF2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs56366346, COSV99223262; called by muse, mutect2, varscan2
- CHRNB4 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs534547966; called by muse, mutect2, varscan2
- CIAO3 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 106/498 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs544946836; called by muse, mutect2, varscan2
- CIITA | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs901729238, COSV60861021, COSV60862314; called by muse, mutect2, varscan2
- CLEC18B | c.994G>A p.G332R | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs751739803; called by muse, mutect2
- CLEC3B | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56110250; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs369752219; called by mutect2, varscan2
- CLSTN3 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as rs775891233, COSV56939630; called by muse, mutect2, varscan2
- COL6A5 | c.3901C>T p.R1301W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs867006064; called by muse, mutect2
- COPS7B | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs778002559, COSV63116321; called by muse, mutect2
- CORO7-PAM16 | c.2804G>C p.G935A | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV52111119; called by muse, mutect2, varscan2
- CPT1B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs916864501, COSV56419070; called by muse, mutect2, varscan2
- CRACD | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 48/556 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs373287876; called by muse, mutect2
- CRB2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756607676, COSV63503090; called by muse, mutect2, varscan2
- CRTC3 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778977437, COSV51597434; called by muse, mutect2, varscan2
- CRYBB1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 111/596 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754411906, COSV53232510; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CUX1 | c.2537C>T p.T846M | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.181); catalogued as rs150188151; called by muse, mutect2, varscan2
- CYFIP1 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138063523; called by muse, mutect2, varscan2
- DACT1 | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs372849027, COSV60019182; called by muse, mutect2, varscan2
- DGKB | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.029); catalogued as COSV99340093; called by muse, mutect2, varscan2
- DGKH | c.1541C>T p.T514M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs761190270, COSV99819334; called by muse, mutect2, varscan2
- DHRSX | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 52/412 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); catalogued as rs768849259, COSV100586101; called by muse, mutect2, varscan2
- DIAPH3 | c.3503C>T p.T1168M | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772731233, COSV64964923; called by muse, varscan2
- DYSF | c.2643C>T p.T881= | Splice Region (SNP) | VAF 27/203 reads (13%) | catalogued as rs750999022, COSV50495888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFS | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs749866850; called by muse, mutect2, varscan2
- EHMT2 | c.1751G>A p.R584Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.394); catalogued as rs1362527213; called by muse, mutect2
- ELF1 | c.896_897dup p.N300* | Frame Shift Ins (INS) | VAF 12/68 reads (18%) | catalogued as rs760268434; called by mutect2, varscan2
- ELOA2 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.19); catalogued as COSV55300898; called by muse, mutect2, varscan2
- ENG | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1410374909, COSV61228210; called by muse, mutect2, varscan2
- ERN2 | c.2305C>T p.R769C | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548992466, COSV55623725; called by muse, mutect2, varscan2
- ETV7 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs151011956; called by muse, mutect2, varscan2
- F2RL3 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 155/744 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs751430141, COSV50186246; called by muse, mutect2, varscan2
- FABP3 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs754575117, COSV65500318; called by muse, mutect2, varscan2
- FAM110A | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV99856668; called by muse, mutect2, varscan2
- FAM228B | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs374474198; called by mutect2, varscan2
- FARS2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149605576, COSV51173755; called by muse, mutect2, varscan2
- FGFR4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs776394759; called by muse, mutect2
- FHOD3 | c.3770G>A p.R1257K (on ENST00000359247 / NM_001281739.3; = p.R1274K on NM_025135.5) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs769012032; called by muse, mutect2, varscan2
- FOXJ2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 44/163 reads (27%) | catalogued as rs1347531364, COSV50822305; called by muse, mutect2, varscan2
- FPR3 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 4/34 reads (12%) | catalogued as rs146700831; called by mutect2, varscan2
- FRAS1 | c.8494G>A p.A2832T | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369335635, COSV53654208; called by muse, mutect2, varscan2
- FREM2 | c.4675G>A p.E1559K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as rs267603820, COSV54839837; called by muse, mutect2, varscan2
- FRMD4A | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV62267437; called by muse, mutect2, varscan2
- FTCD | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs769270784, COSV52428500; called by muse, mutect2
- FXR2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.183); catalogued as COSV51519313; called by muse, mutect2, varscan2
- FXR2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100007092; called by muse, mutect2, varscan2
- GALNT2 | c.80del p.G27Afs*115 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | catalogued as rs1553309006; called by mutect2, pindel, varscan2
- GEMIN5 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.027); catalogued as rs371819928; called by muse, mutect2, varscan2
- GJC2 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 138/535 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778864866, COSV100813016; called by muse, mutect2, varscan2
- GLIS2 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 103/558 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs199849300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR4 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.083); catalogued as rs1297732910; called by muse, mutect2, varscan2
- GRIN2C | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480647979, COSV53115791; called by muse, mutect2, varscan2
- GSTA5 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs1331712732; called by muse, mutect2, varscan2
- GTPBP3 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1437710672, COSV100259041; called by muse, mutect2
- H3C6 | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV64519374; called by muse, mutect2
- HAPLN3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs144444367, COSV62085009, COSV62086111; called by muse, mutect2
- HAPLN4 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 72/332 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as rs1205213971, COSV52270439; called by muse, mutect2, varscan2
- HECW1 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.37); catalogued as rs754513729, COSV67825760, COSV67831887; called by muse, mutect2, varscan2
- HIC1 | c.364del p.A122Lfs*211 (on ENST00000322941 / NM_001098202.1; = p.A103Lfs*211 on NM_006497.4) | Frame Shift Del (DEL) | VAF 56/307 reads (18%) | catalogued as COSV53970024; called by mutect2, pindel, varscan2
- HIVEP2 | c.6932C>T p.S2311L | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as rs866873142, COSV50007211; called by muse, mutect2, varscan2
- HMGXB3 | c.4459C>T p.R1487C (on ENST00000613459; = p.R1241C on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748848300, COSV53827968; called by muse, mutect2, varscan2
- HOXC4 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 56/240 reads (23%) | catalogued as COSV57697535; called by muse, mutect2, varscan2
- HSD17B13 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 28/114 reads (25%) | catalogued as rs376596440; called by muse, mutect2, varscan2
- IDE | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759169186; called by muse, mutect2, varscan2
- IL27RA | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.033); catalogued as rs774377074, COSV54599406; called by muse, mutect2, varscan2
- IP6K2 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.837); catalogued as rs1446074734; called by muse, mutect2, varscan2
- IQSEC1 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs777798451; called by muse, mutect2
- ITGA5 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768546640, COSV53217296; called by muse, mutect2, varscan2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs1181132297; called by mutect2, pindel
- KCNC1 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56392419; called by muse, mutect2, varscan2
- KCNE4 | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56054899; called by muse, mutect2
- KCNG2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs755780837, COSV60270298; called by muse, mutect2, varscan2
- KCP | c.611G>A p.G204D (on ENST00000620378; = p.G261D on NM_001366122.1) | Missense Mutation (SNP) | VAF 59/357 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1462416978; called by muse, mutect2, varscan2
- KIF19 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs553967354; called by muse, mutect2, varscan2
- KIT | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.951); catalogued as rs1309976246, COSV55417440; ClinVar: uncertain significance; called by muse, varscan2
- KLHL2 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1447167194; called by muse, mutect2, varscan2
- KRTAP4-2 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 50/402 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1163498359; called by muse, mutect2, varscan2
- LAMA1 | c.4181G>A p.R1394H | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs373119671; called by muse, varscan2
- LAMA1 | c.4129G>A p.A1377T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs149298173, COSV104432674, COSV67531902; called by muse, varscan2
- LAMB3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 105/478 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762942741, COSV61920286; called by muse, mutect2, varscan2
- LMF1 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs183552168; called by muse, mutect2, varscan2
- LOXL3 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as rs575389607, COSV51207323; called by muse, mutect2, varscan2
- LPCAT1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV52035675; called by muse, mutect2
- LRFN1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as rs1425273957; called by muse, mutect2, varscan2
- LRFN4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs765815973, COSV100540812, COSV58921388; called by muse, mutect2, varscan2
- LRP1 | c.5233G>A p.V1745M | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs755226183, COSV54531383; called by muse, mutect2, varscan2
- MAGI1 | c.2675C>T p.T892M (on ENST00000402939 / NM_001033057.2; = p.T920M on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs750128468; called by muse, mutect2
- MANEAL | c.949G>A p.A317T (on ENST00000373045 / NM_001113482.1; = p.A95T on NM_152496.2) | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs1164811757; called by muse, mutect2, varscan2
- MARCHF10 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376661335; called by muse, mutect2
- MBOAT7 | c.855-3del | Splice Region (DEL) | VAF 10/90 reads (11%) | catalogued as rs756923309; called by mutect2, pindel
- MCF2L | c.1397C>T p.T466M (on ENST00000375608; = p.T434M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs751741111, COSV65047726; called by muse, mutect2
- MCM10 | c.1888C>T p.R630* (on ENST00000484800 / NM_182751.3; = p.R629* on NM_018518.5) | Nonsense Mutation (SNP) | VAF 67/308 reads (22%) | catalogued as rs148160347; called by muse, mutect2, varscan2
- MCM7 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs565560209; called by muse, mutect2, varscan2
- MED16 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 77/397 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1311219214; called by muse, mutect2, varscan2
- MEIS2 | c.809C>T p.P270L (on ENST00000561208 / NM_170675.5; = p.P257L on NM_002399.3) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.922); catalogued as rs369609025, COSV54946965; called by muse, mutect2, varscan2
- MEIS3 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 67/380 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs761325193, COSV100520587; called by muse, mutect2, varscan2
- MKI67 | c.5569del p.I1857Yfs*30 | Frame Shift Del (DEL) | VAF 11/126 reads (9%) | catalogued as rs866533107; called by mutect2, pindel
- MLST8 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs753994134; called by muse, mutect2, varscan2
- MLXIP | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs779013585; called by muse, mutect2, varscan2
- MRGPRX1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs752624994, COSV57107068; called by muse, mutect2, varscan2
- MRPL49 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1565337413; called by muse, mutect2, varscan2
- MSANTD4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs751543630, COSV57285240; called by muse, mutect2, varscan2
- MYCBP2 | c.2458C>T p.R820* (on ENST00000357337; = p.R858* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | catalogued as COSV62011247; called by muse, mutect2, varscan2
- MYH4 | c.4484C>G p.S1495C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV55113531; called by muse, mutect2, varscan2
- MYH7B | c.4090C>T p.R1364W | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs200803656; called by muse, mutect2, varscan2
- NAT8 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs764754413; called by muse, mutect2, varscan2
- NBPF11 | c.2294C>T p.P765L | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.913); catalogued as rs1221652597; called by muse, mutect2, varscan2
- NCAPG2 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1202185010; called by muse, varscan2
- NEB | c.8458T>C p.S2820P | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV51421533; called by muse, mutect2, varscan2
- NIBAN3 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs368873219; called by muse, mutect2, varscan2
- NSMAF | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1311431915; called by muse, mutect2, varscan2
- NTN3 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs560285957; called by muse, mutect2, varscan2
- NUP210 | c.1504G>A p.V502M | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs775075188, COSV54409192; called by muse, mutect2
- OBSCN | c.14746C>T p.R4916W | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs199529556, COSV52742151; called by muse, mutect2, varscan2
- OXER1 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 40/312 reads (13%) | catalogued as rs756362863; called by muse, mutect2, varscan2
- PCDH15 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161238143; called by muse, mutect2, varscan2
- PCDHA5 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65351686; called by muse, mutect2, varscan2
- PCIF1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1222999981, COSV65026081; called by muse, mutect2, varscan2
- PCNX4 | c.1988G>A p.R663H (on ENST00000406854 / NM_001330177.2; = p.R429H on NM_022495.5) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535321266, COSV58302137; called by mutect2, varscan2
- PCSK4 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs139009034; called by muse, mutect2
- PEBP4 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs753786074; called by muse, mutect2, varscan2
- PEPD | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 126/560 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs767798921, COSV54892415; called by muse, mutect2, varscan2
- PER2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs1330427997, COSV54528800; called by muse, mutect2
- PEX16 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs886044625; ClinVar: uncertain significance; called by muse, mutect2
- PHF3 | c.1589G>A p.R530Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs748364798, COSV50315311; called by muse, mutect2, varscan2
- PHLDB1 | c.3853C>T p.R1285C | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs979792101, COSV61877644; called by muse, mutect2, varscan2
- PIEZO2 | c.3821A>C p.N1274T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.971); catalogued as COSV57462610; called by muse, mutect2
- PIK3R2 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as rs751032325, COSV55850197; called by muse, mutect2, varscan2
- PIP5K1A | c.928C>T p.R310C (on ENST00000368888 / NM_001135638.2; = p.R297C on NM_003557.3) | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV62958384; called by muse, mutect2, varscan2
- PKP1 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 75/652 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs781340038, COSV55819938; called by muse, mutect2, varscan2
- PLXNA4 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58139431, COSV58154702; called by muse, mutect2, varscan2
- PML | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.121); catalogued as rs1567115231, COSV51441366; called by muse, mutect2, varscan2
- PNMA5 | c.743T>G p.F248C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1556924379, COSV62626362; called by muse, mutect2, varscan2
- POU5F1 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as rs760434609; called by muse, mutect2
- PRKDC | c.11189C>T p.A3730V | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1388162492, COSV58048857; called by muse, mutect2, varscan2
- PROSER2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV53205631; called by muse, mutect2, varscan2
- PROSER3 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 50/266 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as rs778194260; called by muse, mutect2, varscan2
- PTPRJ | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs374260795, COSV101394690; called by muse, mutect2, varscan2
- PTPRS | c.4714C>T p.R1572W | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs558410776, COSV53613515, COSV53618011; called by muse, mutect2, varscan2
- PUDP | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs368424937; called by muse, mutect2, varscan2
- RABGGTA | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as rs866847893; called by muse, mutect2, varscan2
- RAD9B | c.911del p.K304Rfs*6 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs750814665; called by mutect2, varscan2
- RAI1 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); catalogued as rs1222505115; called by muse, mutect2, varscan2
- RDH13 | c.281G>A p.R94Q (on ENST00000415061 / NM_001145971.2; = p.R23Q on NM_138412.4) | Missense Mutation (SNP) | VAF 42/334 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs370294107; called by muse, mutect2, varscan2
- RNF123 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs528435216; called by muse, mutect2, varscan2
- RNF43 | c.1888T>A p.S630T | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV104435040; called by muse, mutect2, varscan2
- RPUSD4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs1477711924, COSV53599061; called by muse, varscan2
- RTL6 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV57980339; called by muse, mutect2, varscan2
- RTN4RL2 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1444547099; called by muse, mutect2, varscan2
- RYR1 | c.10291G>A p.A3431T | Missense Mutation (SNP) | VAF 85/425 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.424); catalogued as rs553113819, COSV62099194; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL3 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746446415, COSV73306173, COSV73306533; called by muse, mutect2
- SDK2 | c.6302G>A p.S2101N | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1245283370; called by muse, mutect2, varscan2
- SEMA6A | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); catalogued as rs1466749428; called by muse, mutect2
- SESN2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1006193399, COSV53426854; called by muse, mutect2, varscan2
- SHROOM3 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs984582285; called by muse, mutect2, varscan2
- SLC12A7 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 76/407 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150610986; called by muse, mutect2, varscan2
- SLC22A14 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 51/241 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as rs748915002, COSV56198121; called by muse, mutect2, varscan2
- SLC26A1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs756516216; called by muse, mutect2, varscan2
- SLC39A10 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as COSV62769653; called by mutect2, pindel, varscan2
- SLC4A3 | c.3191G>A p.R1064H | Missense Mutation (SNP) | VAF 103/428 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs750234722, COSV99812934, COSV99813184; called by muse, mutect2, varscan2
- SLC6A17 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446781497, COSV100521161; called by muse, mutect2
- SLC9A5 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.533); catalogued as rs1163584484, COSV55361243; called by muse, mutect2, varscan2
- SMAD9 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63204301; called by muse, mutect2, varscan2
- SMG5 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as rs779923631, COSV62437654; called by muse, mutect2, varscan2
- SMOX | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.295); catalogued as rs748652848; called by muse, mutect2, varscan2
- SMOX | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs200727159; called by muse, mutect2
- SNRNP200 | c.4709G>A p.R1570H | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs201294843; called by muse, mutect2, varscan2
- SNX20 | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs757162450, COSV56056827; called by muse, mutect2, varscan2
- SORCS2 | c.3226G>A p.G1076S | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.074); catalogued as rs758161239; called by muse, mutect2, varscan2
- SPEN | c.3040G>A p.V1014M | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs199847404; called by muse, mutect2, varscan2
- SPTLC3 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs775085286, COSV65465332; called by muse, mutect2, varscan2
- SPTY2D1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as rs757488583; called by muse, mutect2, varscan2
- SSTR5 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910862706, COSV53513776; called by muse, mutect2, varscan2
- STOML1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs116083516, COSV57551105; called by muse, mutect2, varscan2
- STRA6 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 26/582 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60585044; called by muse, mutect2
- STX1B | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV53061058; called by muse, mutect2, varscan2
- SYNJ2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770228724; called by muse, mutect2, varscan2
- SYPL2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 55/376 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs750587012, COSV100881555, COSV63995250; called by muse, mutect2, varscan2
- TAOK3 | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as rs764673249; called by muse, mutect2, varscan2
- TAP2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs773291187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCEA3 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs557332428, COSV71531791; called by muse, varscan2
- TCERG1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1212198114, COSV57036884, COSV99694680; called by muse, mutect2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | catalogued as rs763321097; called by mutect2, varscan2
- TEX2 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs782732454, COSV51985789; called by muse, mutect2, varscan2
- TMEM190 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs575894460; called by muse, mutect2, varscan2
- TMEM200C | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1422402189, COSV67309340; called by muse, mutect2
- TMEM39B | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 15/92 reads (16%) | catalogued as rs932727437, COSV100298139; called by muse, mutect2, varscan2
- TRMT1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754093709; called by muse, mutect2, varscan2
- TRPM3 | c.5002C>T p.R1668W (on ENST00000357533 / NM_001366142.2; = p.R1523W on NM_020952.6) | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as rs41287375; called by mutect2, varscan2
- TRPM3 | c.1780C>T p.R594W (on ENST00000357533 / NM_001366142.2; = p.R427W on NM_020952.6) | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1405797336, COSV62582541; called by muse, mutect2
- TSNARE1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as rs532627645; called by muse, mutect2, varscan2
- TTC12 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370336232; called by muse, mutect2, varscan2
- UBR4 | c.8406dup p.M2803Hfs*7 | Frame Shift Ins (INS) | VAF 40/205 reads (20%) | catalogued as rs776496841; called by mutect2, varscan2
- UPF1 | c.1468G>A p.V490M (on ENST00000599848 / NM_001297549.2; = p.V479M on NM_002911.4) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1309527755, COSV53193654; called by muse, mutect2
- USP40 | c.3089G>A p.R1030H | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs750860688; called by muse, varscan2
- USP9Y | c.4807G>A p.G1603R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1317229638; called by muse, mutect2, varscan2
- UTRN | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100840176; called by muse, mutect2
- VANGL1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 92/426 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771534557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VAV2 | c.2308C>T p.R770W (on ENST00000371850 / NM_001134398.2; = p.R760W on NM_003371.4) | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs774443032; called by muse, mutect2, varscan2
- VAV2 | c.1529C>T p.A510V (on ENST00000371850 / NM_001134398.2; = p.A500V on NM_003371.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64080294; called by mutect2, varscan2
- VPS39 | c.2311G>A p.A771T (on ENST00000348544 / NM_001301138.2; = p.A760T on NM_015289.5) | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs147774465; called by muse, mutect2, varscan2
- WDFY3 | c.5503G>A p.V1835I | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs1283763156; called by muse, mutect2
- WDR62 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 121/558 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs751622020, COSV54334763; called by muse, mutect2, varscan2
- WDR62 | c.3674G>A p.R1225H | Missense Mutation (SNP) | VAF 76/428 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs535411065, COSV54333495; called by muse, mutect2, varscan2
- WDR81 | c.1378C>T p.R460W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1420607948; called by muse, mutect2, varscan2
- WDR87 | c.8159del p.K2720Rfs*57 | Frame Shift Del (DEL) | VAF 24/104 reads (23%) | catalogued as rs1555756562; called by mutect2, varscan2
- YWHAG | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1333221474; called by muse, mutect2
- ZNF117 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs1340775301; called by muse, mutect2, varscan2
- ZNF169 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764550642, COSV61765087; called by muse, mutect2, varscan2
- ZNF197 | c.2257C>T p.R753W | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs376273220; called by muse, varscan2
- ZNF334 | c.1242_1244del p.F415del | In Frame Del (DEL) | VAF 14/94 reads (15%) | catalogued as rs769847405; called by pindel, varscan2
- ZNF548 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs376205703; called by muse, mutect2, varscan2
- ZNF551 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.674); catalogued as rs560670635, COSV56592869; called by muse, mutect2, varscan2
- ZNF687 | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs371171135; called by muse, mutect2, varscan2
- ABCA2 | c.4868del p.P1623Hfs*79 (on ENST00000614293; = p.P1593Hfs*79 on NM_001606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ACOX1 | c.1435A>C p.S479R | Missense Mutation (SNP) | VAF 80/330 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRB1 | c.3128A>G p.H1043R | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHR | c.2245A>G p.K749E | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ARID2 | c.2231T>C p.V744A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARL14 | c.211del p.M71* | Frame Shift Del (DEL) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- ASH1L | c.3665del p.K1222Rfs*11 | Frame Shift Del (DEL) | VAF 25/143 reads (17%) | called by mutect2, pindel, varscan2
- ATXN3 | c.224del p.F75Sfs*6 | Frame Shift Del (DEL) | VAF 21/100 reads (21%) | called by mutect2, pindel, varscan2
- BAIAP2L2 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 61/325 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- BEGAIN | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTN2A1 | c.745G>A p.V249M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, varscan2
- C1orf68 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- C2CD2L | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- C6orf89 | c.322T>C p.S108P (on ENST00000373685; = p.S115P on NM_152734.4) | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CACNA1S | c.2752G>A p.V918M | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC146 | c.1207T>C p.S403P | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLCN3 | c.931del p.R311Gfs*14 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel
- CPA2 | c.27del p.F9Lfs*11 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | called by pindel, varscan2
- CRYBA4 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPP1 | c.2162C>T p.A721V (on ENST00000676605; = p.A680V on NM_024790.6) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CUTA | c.172del p.D58Ifs*36 (on ENST00000488034 / NM_001014840.2; = p.D35Ifs*36 on NM_015921.3) | Frame Shift Del (DEL) | VAF 75/384 reads (20%) | called by mutect2, pindel, varscan2
- DDR2 | c.1633A>G p.M545V | Missense Mutation (SNP) | VAF 77/346 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX29 | c.3704A>C p.K1235T | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DIP2B | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DLL3 | c.31T>C p.S11P | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.4919T>C p.L1640P | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DPEP2 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- EGFR | c.797dup p.L267Tfs*32 | Frame Shift Ins (INS) | VAF 50/235 reads (21%) | called by mutect2, pindel, varscan2
- EHMT2 | c.2355del p.W786Gfs*15 | Frame Shift Del (DEL) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- ERICH3 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- EVC | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.271); called by muse, mutect2
- F13A1 | c.397del p.A133Pfs*5 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | called by mutect2, pindel, varscan2
- FAM83C | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 64/436 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- FBXL6 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 53/313 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGL2 | c.242_244del p.E81del | In Frame Del (DEL) | VAF 20/160 reads (13%) | called by pindel, varscan2
- FKBP9 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FNDC1 | c.3841T>C p.Y1281H | Missense Mutation (SNP) | VAF 46/321 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC4 | c.458A>T p.D153V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FOXRED2 | c.2002del p.L668Wfs*111 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | called by mutect2, pindel, varscan2
- FRG2C | c.657T>G p.C219W | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.987); called by muse, mutect2
- FRMPD1 | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAS2L3 | c.2013del p.K671Nfs*16 | Frame Shift Del (DEL) | VAF 15/100 reads (15%) | called by mutect2, pindel, varscan2
- GCLC | c.1275A>C p.R425S (on ENST00000643939; = p.R423S on NM_001498.4) | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- GOLGA8T | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPR62 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GTF2B | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- GTF2F1 | c.167T>A p.I56N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.768); called by muse, mutect2
- GZF1 | c.1521del p.K507Nfs*104 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- IFIT3 | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- IFNL3 | c.529A>C p.N177H | Missense Mutation (SNP) | VAF 49/413 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1-3 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 26/391 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2
- IL1RAP | c.1988del p.P663Lfs*66 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- IL34 | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2
- INAVA | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- IRS2 | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 37/259 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- IZUMO4 | c.89_91del p.S30del | In Frame Del (DEL) | VAF 20/164 reads (12%) | called by mutect2, pindel, varscan2
- KCNK12 | c.208dup p.A70Gfs*393 | Frame Shift Ins (INS) | VAF 26/155 reads (17%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.9307A>G p.T3103A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- KIAA1549 | c.3665T>C p.V1222A | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KIF26B | c.5921G>A p.G1974D | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KNDC1 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- KRT12 | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT31 | c.877-1G>A p.X293_splice | Splice Site (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- LARGE2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- LHFPL1 | c.184A>C p.I62L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- LSG1 | c.1475T>C p.I492T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.101); called by muse, mutect2
- MAGI1 | c.3935C>T p.A1312V | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- MARS2 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MEN1 | c.1736C>A p.A579D | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MGAM2 | c.4383C>G p.I1461M | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MIB1 | c.2986C>T p.R996C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MLLT6 | c.689A>G p.H230R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MMRN2 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 67/276 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MROH7 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH3 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- MYO1B | c.1871A>G p.N624S | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MYO5C | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- NCS1 | c.89+2T>C p.X30_splice | Splice Site (SNP) | VAF 60/505 reads (12%) | called by muse, mutect2, varscan2
- NFE2L3 | c.1174A>T p.I392L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NHLRC1 | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 79/287 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- NIBAN2 | c.2026del p.A676Pfs*77 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- NLN | c.1855C>T p.P619S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- NLRP12 | c.1266del p.L423Cfs*2 | Frame Shift Del (DEL) | VAF 101/518 reads (19%) | called by mutect2, pindel, varscan2
- NR6A1 | c.389T>A p.I130N (on ENST00000487099 / NM_033334.4; = p.I126N on NM_001489.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OBSCN | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- OCA2 | c.67T>G p.S23A | Missense Mutation (SNP) | VAF 29/678 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- OPCML | c.735A>C p.E245D | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- OR10H3 | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- OR3A3 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.12); called by muse, mutect2
- OR8H3 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- OSBPL11 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OTOG | c.4790C>T p.A1597V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.197); called by muse, mutect2
- PACSIN1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCBP2 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA7 | c.1913A>T p.D638V | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- PDE4D | c.1864A>C p.S622R (on ENST00000340635 / NM_001104631.2; = p.S486R on NM_006203.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHKG2 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLB1 | c.3919T>G p.Y1307D | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2
- PLCB2 | c.2333A>G p.H778R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.407); called by muse, mutect2
- PLCH1 | c.1729A>C p.S577R (on ENST00000340059 / NM_001130960.2; = p.S589R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- PODXL2 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.201); called by muse, varscan2
- POU3F4 | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PPP1R21 | c.1817A>G p.N606S | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- PRAM1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PRDM10 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PREX2 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PTH1R | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 24/392 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- RARS2 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- RBM33 | c.2601A>C p.R867S | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RFC1 | c.978_980del p.E327del | In Frame Del (DEL) | VAF 12/80 reads (15%) | called by pindel, varscan2
- RGL4 | c.213dup p.E72Rfs*54 | Frame Shift Ins (INS) | VAF 12/87 reads (14%) | called by mutect2, pindel
- RNF17 | c.4597C>T p.P1533S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2
- RTN4 | c.844A>T p.T282S | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SCAF4 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2
- SEC31A | c.2337_2339del p.I779del (on ENST00000355196 / NM_001318120.1; = p.I740del on NM_016211.4) | In Frame Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel
- SHROOM3 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 72/584 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- SLC38A6 | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A1 | c.1432T>C p.F478L | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- SLC7A1 | c.989T>C p.V330A | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SMC3 | c.350+1G>A p.X117_splice | Splice Site (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2
- SNRNP40 | c.1007A>G p.H336R | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- SOBP | c.1797del p.G600Afs*7 | Frame Shift Del (DEL) | VAF 23/134 reads (17%) | called by mutect2, pindel, varscan2
- SOX1 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEG | c.8194del p.Y2732Tfs*4 | Frame Shift Del (DEL) | VAF 59/270 reads (22%) | called by mutect2, pindel, varscan2
- SPHKAP | c.2695G>C p.V899L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPSB3 | c.595+2T>C p.X199_splice | Splice Site (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- SRRM5 | c.2053A>G p.T685A | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- STAT6 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 40/301 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SUOX | c.440A>C p.H147P | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- SYNCRIP | c.1463A>T p.Y488F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TCIRG1 | c.2350A>G p.T784A | Missense Mutation (SNP) | VAF 116/541 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCTEX1D4 | c.85del p.R29Efs*229 | Frame Shift Del (DEL) | VAF 13/103 reads (13%) | called by mutect2, pindel, varscan2
- TECTA | c.1400A>C p.N467T | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2
- TGFB3 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIRAP | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.394); called by muse, mutect2
- TMEM199 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 133/674 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TPGS1 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- TRGV11 | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.2); called by muse, mutect2
- TRIM64B | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TRIP12 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTYH3 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.174); called by muse, mutect2
- UAP1L1 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBN2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- WARS1 | c.488del p.G163Afs*9 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | called by mutect2, pindel, varscan2
- XPO1 | c.2477T>G p.V826G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- XRCC3 | c.307A>G p.T103A | Missense Mutation (SNP) | VAF 131/646 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF134 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2
- ZNF317 | c.995G>T p.R332M | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF407 | c.1472_1473dup p.T492* | Frame Shift Ins (INS) | VAF 57/312 reads (18%) | called by mutect2, varscan2
- ZNF609 | c.1902dup p.E635Rfs*4 | Frame Shift Ins (INS) | VAF 14/91 reads (15%) | called by mutect2, pindel, varscan2
- ZNF614 | c.142+2T>C p.X48_splice | Splice Site (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- ABAT | c.897T>C p.G299= | Silent (SNP) | VAF 16/508 reads (3%) | called by muse, mutect2
- ABCB9 | c.693C>T p.I231= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs760193984, COSV54894020; called by muse, mutect2, varscan2
- AC011462.1 | c.795C>T p.V265= | Silent (SNP) | VAF 93/417 reads (22%) | catalogued as rs763610087; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTA1 | c.24C>T p.T8= | Silent (SNP) | VAF 67/360 reads (19%) | catalogued as rs762659680, COSV100796781; called by muse, mutect2, varscan2
- ADAMTS16 | c.276C>T p.S92= | Silent (SNP) | VAF 43/422 reads (10%) | catalogued as rs1258075314; called by muse, mutect2
- AGPAT1 | c.579C>T p.G193= | Silent (SNP) | VAF 55/346 reads (16%) | catalogued as rs140902522, COSV61248093; called by muse, mutect2, varscan2
- ALMS1 | c.11214G>A p.R3738= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV100043401; called by muse, mutect2, varscan2
- ALPK3 | c.4290C>T p.Y1430= | Silent (SNP) | VAF 26/408 reads (6%) | catalogued as rs755476608; called by muse, mutect2
- ANKFN1 | c.3414C>T p.S1138= (on ENST00000653862; = p.S991= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/311 reads (8%) | catalogued as rs1041991870; called by muse, mutect2
- ANO1 | c.2535C>T p.N845= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs370309197; called by muse, mutect2, varscan2
- ARHGAP31 | c.1449G>A p.A483= | Silent (SNP) | VAF 34/199 reads (17%) | catalogued as COSV51793109; called by muse, mutect2, varscan2
- ARID1B | c.2109G>A p.A703= | Silent (SNP) | VAF 95/543 reads (17%) | catalogued as rs551597753; called by muse, mutect2, varscan2
- ARMCX1 | c.123C>T p.D41= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs150448743, COSV100863174; called by muse, mutect2, varscan2
- ASH2L | c.1803C>T p.A601= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs778826762; called by muse, mutect2, varscan2
- ATF5 | c.714C>T p.G238= | Silent (SNP) | VAF 45/196 reads (23%) | catalogued as rs140494656; called by muse, mutect2, varscan2
- ATP13A4 | c.1572C>T p.G524= | Silent (SNP) | VAF 32/296 reads (11%) | called by muse, mutect2, varscan2
- ATXN2L | c.792C>T p.Y264= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs578092565; called by mutect2, varscan2
- B3GNT9 | c.747G>A p.A249= | Silent (SNP) | VAF 27/167 reads (16%) | catalogued as rs1321736780; called by muse, mutect2, varscan2
- BSG | c.387C>T p.R129= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1194980049; called by muse, mutect2, varscan2
- C10orf62 | c.162C>T p.S54= | Silent (SNP) | VAF 52/225 reads (23%) | catalogued as rs370827332; called by muse, mutect2, varscan2
- C17orf97 | c.522A>T p.G174= | Silent (SNP) | VAF 41/353 reads (12%) | called by muse, mutect2, varscan2
- C19orf12 | c.360G>A p.A120= (on ENST00000392278 / NM_001031726.3; = p.A109= on NM_031448.6) | Silent (SNP) | VAF 34/177 reads (19%) | catalogued as rs765448305, COSV104405919, COSV60364215; called by muse, mutect2, varscan2
- C1orf35 | c.642C>T p.A214= | Silent (SNP) | VAF 42/235 reads (18%) | catalogued as rs778053863, COSV55254479; called by muse, mutect2, varscan2
- C2orf16 | c.4917C>T p.R1639= | Silent (SNP) | VAF 77/404 reads (19%) | catalogued as rs573465627; called by muse, mutect2, varscan2
- CACNA1C | c.6441C>T p.S2147= (on ENST00000399634 / NM_001167625.1; = p.S2076= on NM_000719.7) | Silent (SNP) | VAF 50/411 reads (12%) | catalogued as rs770654650; called by muse, mutect2, varscan2
- CACNA1I | c.21G>A p.P7= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs778521990, COSV60805062; called by muse, mutect2, varscan2
- CAPZB | c.727C>T p.L243= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- CBX8 | c.1116C>T p.T372= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs753655247, COSV53935325; called by muse, mutect2, varscan2
- CCN4 | c.690C>T p.C230= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as rs150744504; called by muse, mutect2, varscan2
- CHKB | c.507G>A p.T169= | Silent (SNP) | VAF 78/382 reads (20%) | catalogued as rs1344474297; called by muse, mutect2, varscan2
- CIT | c.5463C>T p.D1821= | Silent (SNP) | VAF 45/268 reads (17%) | catalogued as rs376170277; called by muse, mutect2, varscan2
- CKAP5 | c.5053C>T p.L1685= (on ENST00000529230 / NM_001008938.4; = p.L1625= on NM_014756.3) | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- CNOT3 | c.813G>A p.P271= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as rs1245494652, COSV55366463; called by muse, mutect2, varscan2
- COLQ | c.267G>A p.S89= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs144897863; called by muse, mutect2, varscan2
- CPT1A | c.864G>A p.R288= | Silent (SNP) | VAF 24/378 reads (6%) | called by muse, mutect2
- CRTAC1 | c.315C>T p.Y105= | Silent (SNP) | VAF 33/414 reads (8%) | catalogued as rs571436527, COSV53998564; called by muse, mutect2
- CSH2 | c.468C>T p.D156= | Silent (SNP) | VAF 15/236 reads (6%) | catalogued as rs761766182, COSV61081250; called by muse, mutect2
- CTIF | c.1479C>T p.G493= | Silent (SNP) | VAF 39/282 reads (14%) | catalogued as rs1399588508; called by muse, mutect2, varscan2
- CUBN | c.3024G>A p.S1008= | Silent (SNP) | VAF 16/192 reads (8%) | catalogued as rs765777567; called by muse, mutect2
- DMBT1 | c.7533G>A p.S2511= (on ENST00000338354 / NM_001377530.1; = p.S1754= on NM_004406.3) | Silent (SNP) | VAF 94/395 reads (24%) | catalogued as COSV57534807; called by muse, mutect2, varscan2
- DNAH17 | c.6321C>T p.F2107= | Silent (SNP) | VAF 41/258 reads (16%) | catalogued as rs749426170; called by muse, mutect2, varscan2
- DUS3L | c.171C>T p.T57= | Silent (SNP) | VAF 22/410 reads (5%) | called by muse, mutect2
- EEF2KMT | c.6G>A p.A2= | Silent (SNP) | VAF 38/248 reads (15%) | called by muse, varscan2
- EPN2 | c.1290C>T p.G430= | Silent (SNP) | VAF 23/118 reads (19%) | catalogued as rs138168948; called by muse, mutect2, varscan2
- FAM53B | c.1011C>T p.T337= | Silent (SNP) | VAF 39/169 reads (23%) | catalogued as rs778257458, COSV61561705; called by muse, mutect2, varscan2
- FBN1 | c.7719T>C p.G2573= | Silent (SNP) | VAF 17/341 reads (5%) | catalogued as rs1156479272; called by muse, mutect2
- FBXW8 | c.1104C>T p.S368= (on ENST00000309909; = p.S406= on NM_012174.1) | Silent (SNP) | VAF 55/243 reads (23%) | catalogued as rs766875217, COSV99997532; called by muse, mutect2, varscan2
- FOXD4 | c.267G>A p.P89= | Silent (SNP) | VAF 143/800 reads (18%) | catalogued as COSV100070950; called by muse, mutect2, varscan2
- FOXI1 | c.24G>A p.A8= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs781201414, COSV100089549, COSV60388306; called by muse, mutect2, varscan2
- FTCD | c.1479C>T p.G493= | Silent (SNP) | VAF 120/540 reads (22%) | catalogued as rs576503541, COSV52430942; called by muse, mutect2, varscan2
- FTSJ3 | c.1083A>G p.E361= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs769358833; called by muse, varscan2
- FZD9 | c.897C>T p.G299= | Silent (SNP) | VAF 46/299 reads (15%) | catalogued as rs782604885; called by muse, mutect2, varscan2
- GABRG2 | c.810C>T p.G270= (on ENST00000361925 / NM_001375343.1; = p.G230= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as rs747988447, COSV62716657; called by muse, mutect2, varscan2
- GAREM2 | c.609C>T p.G203= | Silent (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- GSDME | c.225G>A p.S75= | Silent (SNP) | VAF 60/419 reads (14%) | catalogued as rs191022542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN4 | c.1125C>T p.G375= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as rs1300164154; called by muse, mutect2
- HPCAL1 | c.270C>T p.S90= | Silent (SNP) | VAF 50/241 reads (21%) | catalogued as rs761311148; called by muse, mutect2, varscan2
- HSPG2 | c.3324C>T p.D1108= | Silent (SNP) | VAF 95/546 reads (17%) | catalogued as rs749208668; called by muse, mutect2, varscan2
- ILVBL | c.1830C>T p.D610= | Silent (SNP) | VAF 97/540 reads (18%) | catalogued as rs141008090; called by muse, mutect2, varscan2
- INPPL1 | c.3009G>A p.S1003= | Silent (SNP) | VAF 49/285 reads (17%) | catalogued as rs1476966843; called by muse, mutect2, varscan2
- INSR | c.3999G>A p.S1333= | Silent (SNP) | VAF 28/130 reads (22%) | catalogued as rs746489788, COSV57166873; called by muse, mutect2, varscan2
- ITLN1 | c.930A>G p.L310= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- KIF2B | c.828C>T p.N276= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as rs1417694993, COSV52130429; called by muse, mutect2
- KREMEN1 | c.693C>T p.P231= (on ENST00000407188; = p.P233= on NM_032045.5) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs376747118; ClinVar: likely benign; called by muse, mutect2, varscan2
- KRT83 | c.744C>T p.Y248= | Silent (SNP) | VAF 78/476 reads (16%) | catalogued as rs761449359, COSV53343424; called by muse, mutect2, varscan2
- LAMB4 | c.78T>C p.G26= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- LMNB2 | c.420C>T p.G140= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as rs751439345; called by muse, mutect2, varscan2
- LRP10 | c.1224C>T p.D408= | Silent (SNP) | VAF 95/586 reads (16%) | catalogued as rs369136828; called by muse, mutect2, varscan2
- MAP3K11 | c.1080G>T p.A360= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV58422125; called by muse, mutect2, varscan2
- MAP7 | c.1689C>T p.R563= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs371285959; called by muse, mutect2, varscan2
- MFSD4B | c.36G>A p.T12= (on ENST00000368847; = p.V108I on NM_153369.4) | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs554182726, COSV64349372; called by muse, mutect2
- MIB2 | c.2331C>T p.N777= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as rs371875401; called by muse, mutect2, varscan2
- MINDY4 | c.2187C>T p.N729= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs200913656, COSV54672464; called by muse, mutect2, varscan2
- MISP3 | c.535C>T p.L179= (on ENST00000269720; = p.L37= on NM_001291291.2) | Silent (SNP) | VAF 45/178 reads (25%) | called by muse, mutect2, varscan2
- MRAS | c.57G>A p.V19= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs1239516898; called by muse, mutect2
- MRPL44 | c.762A>G p.E254= | Silent (SNP) | VAF 33/141 reads (23%) | called by muse, mutect2, varscan2
- MTHFD1L | c.1917C>T p.S639= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as rs772010764; called by muse, mutect2, varscan2
- MUC4 | c.12495C>T p.D4165= | Silent (SNP) | VAF 80/598 reads (13%) | catalogued as rs367924435; called by muse, varscan2
- MVP | c.558C>T p.D186= | Silent (SNP) | VAF 83/299 reads (28%) | catalogued as rs772883962, COSV62421907; called by muse, mutect2, varscan2
- MYO9A | c.6898T>C p.L2300= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs751166373; called by muse, mutect2, varscan2
- NCR3LG1 | c.6G>A p.T2= | Silent (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- NIBAN2 | c.477G>A p.P159= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as rs528460174, COSV100964858; called by muse, mutect2, varscan2
- NIBAN2 | c.345C>T p.A115= | Silent (SNP) | VAF 25/271 reads (9%) | catalogued as rs370542607; called by muse, mutect2, varscan2
- NOTCH4 | c.552G>A p.P184= | Silent (SNP) | VAF 68/333 reads (20%) | catalogued as rs151181251; called by muse, mutect2, varscan2
- NPC1 | c.336A>G p.T112= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs765319175, COSV52577473; called by muse, mutect2, varscan2
- NPHP4 | c.48C>A p.P16= | Silent (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- NR2F6 | c.1176G>A p.S392= | Silent (SNP) | VAF 56/344 reads (16%) | catalogued as rs761842500; called by muse, mutect2, varscan2
- P2RX6 | c.1236G>A p.T412= | Silent (SNP) | VAF 110/560 reads (20%) | catalogued as rs556277237; called by muse, mutect2, varscan2
- PABPC4 | c.1215G>A p.A405= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs201347429, COSV100790875; called by muse, mutect2, varscan2
- PAMR1 | c.159C>T p.C53= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs1162976422, COSV53512371; called by muse, mutect2, varscan2
- PCDHA13 | c.2292G>A p.P764= | Silent (SNP) | VAF 58/235 reads (25%) | catalogued as COSV56549255, COSV99169757; called by muse, mutect2, varscan2
- PFKFB4 | c.675C>T p.Y225= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs763661697; called by muse, mutect2
- PGLS | c.426C>T p.F142= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as rs775150834; called by muse, mutect2, varscan2
- PIK3CG | c.714C>T p.D238= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as rs778266273; called by muse, mutect2, varscan2
- PKDCC | c.708C>T p.G236= | Silent (SNP) | VAF 26/124 reads (21%) | catalogued as rs772243421; called by muse, mutect2, varscan2
- PLEKHG4 | c.2007C>T p.H669= | Silent (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- PPM1E | c.1686C>T p.N562= | Silent (SNP) | VAF 18/190 reads (9%) | catalogued as rs780978666; called by muse, mutect2
- PREP | c.738C>T p.R246= (on ENST00000369110; = p.R312= on NM_002726.5) | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as rs147800201; called by muse, mutect2, varscan2
- PRF1 | c.565C>T p.L189= | Silent (SNP) | VAF 17/185 reads (9%) | called by muse, mutect2
- PRKACG | c.9C>T p.N3= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs764485591; called by muse, mutect2
- PRRC2C | c.7416G>A p.Q2472= (on ENST00000367742; = p.Q2470= on NM_015172.4) | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- PTPN14 | c.1887G>A p.T629= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as rs552872709, COSV100872564; called by muse, mutect2, varscan2
- RAB11FIP3 | c.927G>A p.A309= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs147525736; called by muse, mutect2, varscan2
- RAPGEF3 | c.1386G>A p.R462= (on ENST00000389212; = p.R420= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as rs1298568485; called by muse, mutect2
- RARB | c.546T>G p.A182= (on ENST00000383772 / NM_001290216.2; = p.A175= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- RND1 | c.435G>A p.A145= | Silent (SNP) | VAF 59/380 reads (16%) | catalogued as rs1422048821, COSV59044838; called by muse, mutect2, varscan2
- RNF208 | c.597C>T p.Y199= | Silent (SNP) | VAF 56/252 reads (22%) | catalogued as rs767078963; called by muse, mutect2, varscan2
- SEMA6C | c.1851C>T p.G617= | Silent (SNP) | VAF 33/268 reads (12%) | catalogued as rs1227403496, COSV59007905; called by muse, mutect2, varscan2
- SERPINA4 | c.252G>A p.A84= | Silent (SNP) | VAF 32/542 reads (6%) | catalogued as rs767013382, COSV54070381; called by muse, mutect2
- SESTD1 | c.1584C>T p.G528= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs758652669, COSV58930601; called by muse, mutect2, varscan2
- SIGLEC11 | c.1875G>A p.P625= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs752276631; called by muse, mutect2, varscan2
- SIGLEC15 | c.522G>A p.S174= | Silent (SNP) | VAF 34/320 reads (11%) | called by muse, mutect2
- SIPA1L1 | c.2943T>C p.G981= | Silent (SNP) | VAF 107/571 reads (19%) | called by muse, mutect2, varscan2
- SIRT5 | c.357C>T p.R119= | Silent (SNP) | VAF 28/393 reads (7%) | catalogued as rs199860001; called by muse, mutect2
- SLC12A8 | c.582A>C p.T194= | Silent (SNP) | VAF 36/258 reads (14%) | called by muse, mutect2, varscan2
- SLC25A31 | c.48C>T p.D16= | Silent (SNP) | VAF 42/366 reads (11%) | catalogued as rs761883245, COSV55418278; called by muse, mutect2, varscan2
- SLC25A47 | c.342G>A p.S114= | Silent (SNP) | VAF 104/475 reads (22%) | catalogued as rs377238447; called by muse, mutect2, varscan2
- SLCO3A1 | c.1818G>A p.T606= | Silent (SNP) | VAF 23/177 reads (13%) | catalogued as rs144388319, COSV59226842; called by muse, mutect2, varscan2
- SLX4 | c.4056G>A p.P1352= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs768415277; called by muse, mutect2, varscan2
- SPANXB1 | c.129T>G p.P43= | Silent (SNP) | VAF 17/520 reads (3%) | called by muse, mutect2
- SPATA31E1 | c.4008A>G p.G1336= | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- STK19 | c.147C>T p.V49= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs772325009, COSV61715327; called by muse, mutect2, varscan2
- SYCE2 | c.171A>G p.G57= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- TAF1 | c.3396C>T p.S1132= (on ENST00000373790 / NM_138923.4; = p.S1153= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/100 reads (41%) | catalogued as rs1314628439; called by muse, mutect2, varscan2
- TEDC1 | c.942G>A p.A314= (on ENST00000392523 / NM_001367178.1; = p.A245= on NM_001134875.1) | Silent (SNP) | VAF 63/399 reads (16%) | catalogued as rs140894619; called by muse, mutect2, varscan2
- THSD4 | c.198G>A p.S66= | Silent (SNP) | VAF 67/270 reads (25%) | called by muse, mutect2, varscan2
- TMEM240 | c.342C>T p.A114= | Silent (SNP) | VAF 24/407 reads (6%) | catalogued as rs532021282; called by muse, mutect2
- TNRC18 | c.825G>A p.A275= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- TULP4 | c.297G>A p.T99= | Silent (SNP) | VAF 34/139 reads (24%) | catalogued as rs1055958559, COSV65575968; called by muse, mutect2, varscan2
- ULK1 | c.1962G>A p.T654= | Silent (SNP) | VAF 12/312 reads (4%) | catalogued as rs914416175; called by muse, mutect2
- UNC5B | c.789C>T p.G263= | Silent (SNP) | VAF 12/147 reads (8%) | called by muse, mutect2
- USP38 | c.2820A>G p.T940= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- USP7 | c.2871A>G p.E957= | Silent (SNP) | VAF 18/117 reads (15%) | called by muse, varscan2
- VPS4A | c.978G>A p.T326= | Silent (SNP) | VAF 68/671 reads (10%) | catalogued as rs772873947; called by muse, mutect2, varscan2
- WDR6 | c.1392C>T p.C464= | Silent (SNP) | VAF 22/292 reads (8%) | called by muse, mutect2
- WDR93 | c.945C>T p.S315= | Silent (SNP) | VAF 27/171 reads (16%) | catalogued as rs754921046; called by muse, mutect2, varscan2
- ZFHX3 | c.4302T>C p.C1434= | Silent (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- ZMYM1 | c.1494C>T p.H498= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs939240953; called by muse, mutect2, varscan2
- ZNF219 | c.1602G>A p.A534= | Silent (SNP) | VAF 86/464 reads (19%) | catalogued as COSV53883636; called by muse, mutect2, varscan2
- ZNF276 | c.945C>T p.D315= (on ENST00000443381 / NM_001113525.2; = p.D240= on NM_152287.4) | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs771288582, COSV57067796, COSV99235273; called by muse, mutect2, varscan2
- ZNF362 | c.798C>T p.N266= | Silent (SNP) | VAF 113/543 reads (21%) | catalogued as rs752377856; called by muse, mutect2, varscan2
- ZNF366 | c.741C>T p.G247= | Silent (SNP) | VAF 117/571 reads (20%) | catalogued as rs776841489, COSV100574149; called by muse, mutect2, varscan2
- ZNF568 | c.936A>G p.E312= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- ZNF816 | c.486G>A p.S162= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as rs759711978, COSV54412837; called by muse, varscan2
- AC012236.1 | n.276G>A | RNA (SNP) | VAF 15/34 reads (44%) | catalogued as rs527759454; called by muse, mutect2, varscan2
- AC133561.1 | n.1896C>T | RNA (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.5183-15G>A | Intron (SNP) | VAF 61/339 reads (18%) | catalogued as rs779534633; called by muse, mutect2, varscan2
- AFAP1 | c.1531-2521G>A | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as rs370852242; called by muse, mutect2, varscan2
- AGAP3 | c.224-1688G>C | Intron (SNP) | VAF 31/162 reads (19%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1504G>A | Intron (SNP) | VAF 11/94 reads (12%) | catalogued as rs200497981; called by muse, mutect2, varscan2
- ALG2 | c.348+411C>T | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, varscan2
- AP000769.3 | chr11:65501804 T>C | 5'Flank (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- BANP | c.1345-141C>T | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as rs773511127; called by muse, mutect2, varscan2
- BDNF | chr11:27700973 ins C | 5'Flank (INS) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- C2CD6 | c.1581+2023del | Intron (DEL) | VAF 4/46 reads (9%) | called by pindel, varscan2
- CACNB1 | c.1332+10C>A | Intron (SNP) | VAF 68/333 reads (20%) | called by muse, mutect2, varscan2
- CENPM | c.231-28T>G | Intron (SNP) | VAF 34/216 reads (16%) | called by muse, mutect2
- CPLANE1 | chr5:37167048 del T | 3'Flank (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- CSNK1G2 | c.*37C>T | 3'UTR (SNP) | VAF 16/129 reads (12%) | catalogued as rs563758255; called by mutect2, varscan2
- CTSLP8 | n.931C>G | RNA (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- DARS2 | c.1674+38del | Intron (DEL) | VAF 15/78 reads (19%) | called by mutect2, pindel, varscan2
- DCHS2 | n.5394dup | RNA (INS) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- DECR2 | c.201+282del | Intron (DEL) | VAF 6/24 reads (25%) | catalogued as rs1414125225; called by mutect2, varscan2
- DMTN | c.295-16C>T | Intron (SNP) | VAF 12/93 reads (13%) | catalogued as rs376084791, COSV56112882; called by muse, mutect2, varscan2
- DNAH2 | c.1904+385G>A | Intron (SNP) | VAF 3/9 reads (33%) | catalogued as rs998723356; called by muse, mutect2
- DNAH5 | c.799-40C>T | Intron (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- ETFDH | c.487+32G>A | Intron (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- FBRS | chr16:30664344 G>A | 5'Flank (SNP) | VAF 14/42 reads (33%) | catalogued as rs993463167, COSV54918310; called by muse, mutect2, varscan2
- FOXP1 | c.1146+32del | Intron (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- GLI3 | c.125-24165C>T | Intron (SNP) | VAF 18/212 reads (8%) | catalogued as rs756074638, COSV101229706; called by muse, mutect2
- GTF2H1 | c.*6C>T | 3'UTR (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2, varscan2
- GUCY2D | c.2413-38G>T | Intron (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- GUCY2EP | n.937G>A | RNA (SNP) | VAF 31/262 reads (12%) | catalogued as rs1419456596; called by muse, mutect2, varscan2
- HAPLN4 | c.-21G>A | 5'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- HGD | c.1007-230C>T | Intron (SNP) | VAF 15/97 reads (15%) | catalogued as rs182166673; called by muse, mutect2, varscan2
- HGS | c.537+20del | Intron (DEL) | VAF 16/114 reads (14%) | called by mutect2, pindel, varscan2
- IFNGR2 | c.74-3384C>T | Intron (SNP) | VAF 18/220 reads (8%) | catalogued as rs1215884789; called by muse, mutect2
- IGHG3 | c.*37C>T | 3'UTR (SNP) | VAF 56/313 reads (18%) | called by muse, mutect2, varscan2
- IL34 | c.-14C>T | 5'UTR (SNP) | VAF 30/147 reads (20%) | catalogued as rs761784434; called by muse, mutect2, varscan2
- INPP4A | c.-34G>A | 5'UTR (SNP) | VAF 14/107 reads (13%) | catalogued as rs370042428; called by muse, mutect2, varscan2
- IQCN | c.2617-205C>A | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- KCNG1 | c.*2C>T | 3'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as rs773386495, COSV65369048; called by muse, mutect2, varscan2
- KCNH2 | c.1945+25C>T | Intron (SNP) | VAF 53/243 reads (22%) | catalogued as rs377215925; called by muse, mutect2, varscan2
- KLF6 | c.*382del | 3'UTR (DEL) | VAF 27/158 reads (17%) | called by mutect2, pindel, varscan2
- KLHL29 | c.940+128T>C | Intron (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- LBX2 | chr2:74502675 C>T | 5'Flank (SNP) | VAF 24/290 reads (8%) | catalogued as rs773257709; called by muse, mutect2
- LINC01548 | n.548G>A | RNA (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- LINC02054 | n.2595-11572dup | Intron (INS) | VAF 27/216 reads (13%) | catalogued as rs1314261619; called by mutect2, varscan2
- LRRC1 | c.446+1033A>G | Intron (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- LRRC49 | c.194-2489G>A | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- MAFF | c.*162del | 3'UTR (DEL) | VAF 4/20 reads (20%) | catalogued as rs770831565; called by mutect2, pindel
- MARCHF5 | c.-25G>A | 5'UTR (SNP) | VAF 66/412 reads (16%) | catalogued as rs964781371; called by muse, mutect2, varscan2
- MDM4 | c.412-209del | Intron (DEL) | VAF 14/72 reads (19%) | catalogued as rs752620801; called by mutect2, varscan2
- MFN2 | c.600-18del | Intron (DEL) | VAF 37/236 reads (16%) | called by mutect2, pindel, varscan2
- MFRP | chr11:119344877 G>A | 5'Flank (SNP) | VAF 89/443 reads (20%) | catalogued as rs771487710, COSV64127953, COSV64128712; called by muse, mutect2, varscan2
- MTFR1L | chr1:25820515 T>C | 5'Flank (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- NOM1 | c.1911+44del | Intron (DEL) | VAF 41/294 reads (14%) | catalogued as rs764951294; called by mutect2, varscan2
- PDIA3P1 | chr1:147179255 T>C | 3'Flank (SNP) | VAF 52/210 reads (25%) | called by muse, mutect2, varscan2
- PPP1R16A | c.259+534C>T | Intron (SNP) | VAF 11/53 reads (21%) | catalogued as rs777410270; called by muse, mutect2, varscan2
- RNF44 | c.1237-82G>A | Intron (SNP) | VAF 14/175 reads (8%) | catalogued as rs760054020; called by muse, mutect2
- RPL10 | c.191-39_191-35del | Intron (DEL) | VAF 5/49 reads (10%) | catalogued as rs1557185419; called by mutect2, varscan2
- RUNX2 | c.-10del | 5'UTR (DEL) | VAF 28/134 reads (21%) | catalogued as rs748951752; called by mutect2, varscan2
- SAMHD1 | c.1504-485del | Intron (DEL) | VAF 12/97 reads (12%) | called by mutect2, pindel, varscan2
- SMARCA4 | c.2617-139C>T | Intron (SNP) | VAF 11/199 reads (6%) | catalogued as rs1375256677; called by muse, mutect2
- SNORD115-23 | n.64A>G | RNA (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2
- SNX8 | c.*1C>T | 3'UTR (SNP) | VAF 64/367 reads (17%) | catalogued as rs1253365665, COSV56125522; called by muse, mutect2, varscan2
- SPAG7 | c.574+16G>T | Intron (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- ST3GAL3 | c.348-15057del | Intron (DEL) | VAF 25/99 reads (25%) | catalogued as rs749241072; called by mutect2, varscan2
- TBC1D22A | c.1015+3293C>T | Intron (SNP) | VAF 37/212 reads (17%) | catalogued as rs760403704; called by muse, mutect2, varscan2
- TBCD | c.2039-49G>A | Intron (SNP) | VAF 12/109 reads (11%) | catalogued as rs752856067, COSV62803777; called by muse, mutect2, varscan2
- TNIP1 | c.*617C>T | 3'UTR (SNP) | VAF 40/592 reads (7%) | catalogued as rs975133434; called by muse, mutect2
- TRA2A | c.*34_*39delinsCCTC | 3'UTR (DEL) | VAF 4/45 reads (9%) | called by pindel, varscan2*
- TRDN | c.-39C>T | 5'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs772263581, COSV62132997; called by muse, mutect2, varscan2
- UMPS | c.*3440C>G | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- UNC13D | c.951+29C>T | Intron (SNP) | VAF 39/331 reads (12%) | catalogued as rs567337692; called by muse, mutect2, varscan2
- WAC | c.42-47del | Intron (DEL) | VAF 11/94 reads (12%) | catalogued as rs977694462; called by mutect2, pindel, varscan2
- WT1 | chr11:32440032 del A | 5'Flank (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- XIAP | c.*5630C>T | 3'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- ZNF732 | c.-22G>A | 5'UTR (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
